Somatic mutation profile of tumor specimen TCGA-A3-3358-01A (aliquot TCGA-A3-3358-01A-01D-1534-10) from TCGA case TCGA-A3-3358, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 57.7 years (21,087 days).
Specimen TCGA-A3-3358-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34daa316-229a-4615-afc0-f666e69b5fb8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3358-11A (Solid Tissue Normal), aliquot TCGA-A3-3358-11A-01D-1534-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3bd2a66c-3c40-4a5b-b1cf-302c961fa1f5

The open-access MAF lists 68 somatic variants for this specimen: 51 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 16, Nonsense Mutation 5, Frame Shift Del 3, Splice Site 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1BG | c.347T>A p.L116* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV54050465; called by muse, mutect2
- ATRX | c.6928C>A p.P2310T | Missense Mutation (SNP) | VAF 91/479 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as COSV64874348; called by muse, mutect2, varscan2
- CCL27 | c.75C>A p.F25L | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52404765; called by muse, mutect2, varscan2
- CDC7 | c.749C>T p.S250F | Missense Mutation (SNP) | VAF 96/381 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.144); catalogued as COSV52310128; called by muse, mutect2, varscan2
- CEP95 | c.409C>A p.R137S | Missense Mutation (SNP) | VAF 79/582 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0.019); catalogued as COSV73608943, COSV73609693; called by mutect2, varscan2
- CPEB1 | c.1374C>G p.S458R (on ENST00000617958; = p.S393R on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55618119; called by muse, mutect2, varscan2
- CSNK1G3 | c.759G>T p.K253N | Missense Mutation (SNP) | VAF 243/1367 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62054092; called by muse, mutect2, varscan2
- DNAH9 | c.3441G>T p.E1147D | Missense Mutation (SNP) | VAF 51/246 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV52343855; called by muse, mutect2, varscan2
- EPM2A | c.901C>A p.P301T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV62295847, COSV62295928; called by muse, mutect2, varscan2
- ERCC3 | c.1561G>T p.E521* | Nonsense Mutation (SNP) | VAF 61/254 reads (24%) | catalogued as COSV53426503; called by muse, mutect2, varscan2
- EXOC7 | c.568C>T p.H190Y | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV58740774; called by muse, mutect2
- FAM71C | c.296G>C p.R99T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV60942957; called by muse, mutect2
- FN1 | c.2004C>G p.I668M | Missense Mutation (SNP) | VAF 81/325 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60549821; called by muse, mutect2, varscan2
- FRAS1 | c.9134A>C p.E3045A | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53601591; called by muse, mutect2, varscan2
- G2E3 | c.1026T>G p.F342L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV52839484; called by muse, varscan2
- GABRG2 | c.958T>A p.Y320N (on ENST00000361925 / NM_001375343.1; = p.Y280N on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/698 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62716835; called by muse, mutect2
- GLDN | c.867T>A p.D289E | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.031); catalogued as COSV59089493; called by muse, mutect2, varscan2
- GPC3 | c.1037G>T p.G346V | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.348); catalogued as rs373916851, COSV63661879; ClinVar: likely benign; called by mutect2, varscan2
- GPX4 | c.521G>C p.G174A | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62319664; called by muse, mutect2, varscan2
- HMCN1 | c.4999G>T p.G1667* | Nonsense Mutation (SNP) | VAF 55/253 reads (22%) | catalogued as COSV54889867; called by muse, mutect2, varscan2
- HTR1E | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs771278269, COSV59507451; called by muse, mutect2, varscan2
- KANSL1L | c.2531G>A p.W844* | Nonsense Mutation (SNP) | VAF 151/629 reads (24%) | catalogued as COSV55990942, COSV55991984; called by muse, mutect2, varscan2
- MAGEB10 | c.712C>A p.H238N | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.575); catalogued as COSV63310813; called by muse, mutect2, varscan2
- MCM7 | c.1078G>A p.G360R | Missense Mutation (SNP) | VAF 151/410 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781137780, COSV57995361, COSV57999069; called by muse, mutect2, varscan2
- MROH9 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 115/544 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV63010734; called by muse, mutect2, varscan2
- MRPL48 | c.275A>G p.N92S | Missense Mutation (SNP) | VAF 98/422 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs749814518, COSV58638916; called by muse, mutect2, varscan2
- NUAK1 | c.601A>G p.N201D | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54602108; called by muse, mutect2
- PCDHB5 | c.2247C>A p.H749Q | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV50649230; called by muse, mutect2, varscan2
- PIP5K1A | c.656del p.P219Lfs*25 (on ENST00000368888 / NM_001135638.2; = p.P206Lfs*25 on NM_003557.3) | Frame Shift Del (DEL) | VAF 36/190 reads (19%) | catalogued as COSV62960498; called by mutect2, pindel, varscan2
- PSG5 | c.635C>G p.T212R | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as COSV61653979; called by muse, mutect2, varscan2
- RRP1B | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 12/327 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); catalogued as COSV61478790; called by muse, mutect2
- SETBP1 | c.1190C>T p.S397L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV56317934; called by muse, mutect2, varscan2
- SETD2 | c.7239-2A>T p.X2413_splice | Splice Site (SNP) | VAF 30/101 reads (30%) | catalogued as COSV57434559; called by muse, mutect2, varscan2
- SIM2 | c.645G>C p.Q215H | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV99292956; called by muse, mutect2, varscan2
- SLC12A4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV57927648; called by muse, mutect2, varscan2
- SLC12A4 | c.1647G>T p.K549N | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.324); catalogued as rs184951084, COSV57927683; called by muse, mutect2, varscan2
- SPEN | c.2770C>T p.P924S | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV65360090; called by muse, mutect2, varscan2
- SPTA1 | c.4822C>T p.R1608C | Missense Mutation (SNP) | VAF 164/703 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1279138950, COSV100935674, COSV63751266; called by muse, mutect2, varscan2
- SUN5 | c.903G>A p.M301I | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV62180632; called by muse, mutect2, varscan2
- TMEM150A | c.154G>A p.G52R (on ENST00000334462 / NM_001031738.3; = p.K21= on NM_153342.3) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.063); catalogued as COSV57817670; called by muse, mutect2, varscan2
- UHRF1 | c.1709A>G p.K570R (on ENST00000612630 / NM_001290050.1; = p.K583R on NM_013282.4) | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV53573805; called by muse, mutect2, varscan2
- UNC45B | c.1337T>G p.I446S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52094046; called by muse, mutect2, varscan2
- WNK3 | c.2594C>A p.S865* | Nonsense Mutation (SNP) | VAF 30/140 reads (21%) | catalogued as COSV63612956; called by muse, mutect2, varscan2
- YBX3 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371143914; called by muse, mutect2, varscan2
- ZNF429 | c.1990A>T p.I664F | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV61915519; called by muse, mutect2, varscan2
- ZNF75D | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs370618867, COSV66132596; called by muse, mutect2, varscan2
- ZSWIM8 | c.64T>G p.F22V | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV65708191; called by muse, mutect2, varscan2
- LLGL1 | c.2051dup p.L685Vfs*10 | Frame Shift Ins (INS) | VAF 9/26 reads (35%) | called by mutect2, pindel, varscan2
- PCGF2 | c.637T>A p.Y213N | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SSH2 | c.3489_3492del p.S1163Rfs*18 | Frame Shift Del (DEL) | VAF 26/162 reads (16%) | called by mutect2, pindel, varscan2
- WDR44 | c.801_820del p.E267Dfs*11 | Frame Shift Del (DEL) | VAF 21/168 reads (13%) | called by mutect2, pindel, varscan2
- ANXA10 | c.363T>C p.N121= | Silent (SNP) | VAF 68/454 reads (15%) | catalogued as rs955646470, COSV63738643; called by muse, mutect2
- BCCIP | c.576T>G p.A192= | Silent (SNP) | VAF 26/146 reads (18%) | catalogued as COSV52939267; called by muse, mutect2
- CHMP7 | c.978G>A p.Q326= | Silent (SNP) | VAF 49/183 reads (27%) | catalogued as COSV57532678; called by muse, mutect2, varscan2
- ERCC6L | c.2445A>T p.P815= | Silent (SNP) | VAF 87/352 reads (25%) | catalogued as COSV57820164; called by muse, mutect2, varscan2
- GALNT6 | c.933C>G p.P311= | Silent (SNP) | VAF 46/136 reads (34%) | catalogued as COSV62542202, COSV62542435; called by muse, mutect2
- GPD2 | c.1542G>A p.V514= | Silent (SNP) | VAF 28/356 reads (8%) | catalogued as rs370358716; called by muse, mutect2
- GPX4 | c.522C>T p.G174= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs763436287, COSV62319667; called by muse, mutect2, varscan2
- KIF21B | c.4842C>T p.Y1614= (on ENST00000422435 / NM_001252100.2; = p.Y1601= on NM_017596.4) | Silent (SNP) | VAF 27/126 reads (21%) | catalogued as rs746518366, COSV59755357; called by muse, mutect2, varscan2
- MICAL2 | c.2979C>T p.P993= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as COSV56318873; called by muse, varscan2
- NENF | c.381G>A p.E127= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as COSV65341145; called by muse, mutect2, varscan2
- PASK | c.897T>C p.S299= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99298850; called by muse, mutect2
- PKNOX1 | c.72A>G p.L24= | Silent (SNP) | VAF 30/150 reads (20%) | catalogued as COSV52335145; called by muse, mutect2, varscan2
- TLCD3B | c.705C>T p.N235= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV54226654; called by muse, mutect2, varscan2
- UNC13A | c.2241C>T p.D747= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as rs373430076; called by muse, mutect2, varscan2
- WAS | c.525A>T p.P175= | Silent (SNP) | VAF 29/142 reads (20%) | catalogued as CD134560, COSV64996843; called by muse, mutect2, varscan2
- YLPM1 | c.1905C>T p.P635= | Silent (SNP) | VAF 42/178 reads (24%) | catalogued as COSV53109462; called by muse, mutect2, varscan2
- SEPTIN6 | c.690+3198G>A | Intron (SNP) | VAF 35/163 reads (21%) | catalogued as COSV59713287; called by muse, mutect2, varscan2
